Somatic mutation profile of tumor specimen 0DMBMB from CCDI case PBCAGI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.6 years (1,304 days).
Specimen 0DMBMB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0611d986-3b67-4270-8874-69be3f557c32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DMBLJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e7f0238-3a4c-4322-b2c8-6a248f8f4287

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ZC3H3 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 20/739 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs144112744; called by muse, mutect2
- CREBZF | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 32/926 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); called by muse, mutect2
- DDX47 | c.304C>G p.R102G | Missense Mutation (SNP) | VAF 264/836 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PWWP2A | c.2215G>A p.A739T | Missense Mutation (SNP) | VAF 51/592 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.291); called by muse, mutect2
- SLC5A7 | c.1713A>T p.E571D | Missense Mutation (SNP) | VAF 17/548 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- MC2R | c.-49G>A | 5'UTR (SNP) | VAF 28/493 reads (6%) | catalogued as rs200249547; called by muse, mutect2
